CCDI case PBCKXG — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Adrenal gland.
https://portal.gdc.cancer.gov/cases/12888ad9-11cd-4b56-b44a-d1d26a63af7e

Demographics
Sex at birth: male; Race: asian.

Diagnoses (1)
1. Pheochromocytoma, NOS: ICD-O-3 morphology code: 8700/0; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 7.0 years (2,540 days).

Biospecimens (3 samples)
- Sample 0DVDTA: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DVDU8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DVDUW: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
